Gene-level copy-number profile of tumor specimen HTMCP-03-06-02075-01A from CGCI case HTMCP-03-06-02075, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 54.4 years (19,868 days).
Specimen HTMCP-03-06-02075-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d84217a7-cf27-4606-b559-053241d24752.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02075-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/8a1d6bd7-cf22-4e65-9c0d-3065a4a10276

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 3,675; copy number 2: 36,614; copy number 3: 10,726; copy number 4: 4,148; copy number 5: 2,451; copy number 6: 439; copy number 7: 77; copy number 8: 185; copy number 9: 10; copy number 10: 34; copy number 11: 3; copy number 13: 5; copy number 17: 9.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,524,185, 5 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr9:39,748,514–39,810,097, 2 genes: GLIDR, BX664615.1.
- chr9:39,816,599–39,874,562, 1 gene (within-gene range 0–1): BX664615.2.
- chr22:21,167,758–21,294,586, 8 genes (within-gene range 0–3): FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P, BCRP6.
- chr22:21,341,595–21,345,258, 1 gene: PPP1R26P5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,213 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,938,744–147,909,269, 32 genes, copy number 5–6: NBPF12, PFN1P8, AC244394.3, AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8.
- chr1:150,045,660–150,145,329, 3 genes, copy number 8: AC244033.2, AC244033.1, VPS45.
- chr1:150,487,364–151,729,805, 73 genes, copy number 5–8 (broad region; genes not listed).
- chr1:151,982,915–154,288,527, 134 genes, copy number 6–11 (broad region; genes not listed).
- chr1:166,763,334–166,856,359, 3 genes, copy number 7: FMO11P, CNN2P10, POGK.
- chr2:38,814–5,719,670, 78 genes, copy number 5 (broad region; genes not listed).
- chr2:5,810,641–96,740,064, 1,610 genes, copy number 5–11 (broad region; genes not listed).
- chr6:29,934,101–29,934,286, 1 gene, copy number 6: HLA-U.
- chr12:48,627,879–49,094,801, 35 genes, copy number 6: OR11M1P, KANSL2, SNORA2C, MIR1291, SNORA2A, SNORA2B, CCNT1, TEX49, AC117498.1, ADCY6, MIR4701, ADCY6-DT, AC117498.2, Y_RNA, CACNB3, DDX23, RND1, RNU6-600P, AC073610.1, AC073610.2, CCDC65, FKBP11, ARF3, WNT10B, RNU6-940P, WNT1, DDN, AC011603.3, DDN-AS1, PRKAG1, KMT2D, RHEBL1, AC011603.4, DHH, AC011603.1.
- chr12:51,590,266–51,812,864, 2 genes, copy number 5 (within-gene range 2–5): SCN8A, HNRNPA3P10.
- chr14:18,333,726–19,003,752, 30 genes, copy number 5–7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P.
- chr14:19,920,582–19,957,996, 3 genes, copy number 6: OR4K5, OR4K1, OR4K16P.
- chr14:22,147,995–22,190,713, 7 genes, copy number 17: TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33.
- chr14:22,202,583–22,208,129, 2 genes, copy number 17: TRAV26-2, TRAV34.
- chr19:17,231,883–17,521,288, 28 genes, copy number 6–7 (within-gene range 4–7): NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3, TMEM221, AC010319.2, AC010319.5, NXNL1, SLC27A1, AC010618.3, PGLS.
- chr19:27,638,483–28,727,777, 26 genes, copy number 5–6: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1.
- chr19:40,991,282–41,881,372, 56 genes, copy number 5–6: CYP2B6, CYP2A7P1, CYP2G2P, AC008962.1, CYP2A13, CYP2F1, CYP2T3P, RPL36P16, RN7SL718P, CYP2S1, AXL, AC011510.1, HNRNPUL1, RN7SL34P, TGFB1, AC011462.5, CCDC97, AC011462.1, TMEM91, B9D2, AC011462.4, EXOSC5, BCKDHA, AC011462.3, AC011462.2, B3GNT8, DMAC2, Metazoa_SRP, ERICH4, PCAT19, AC243960.2, PLEKHA3P1, AC243960.3, LINC01480, AC243960.1, CEACAM21, AC243960.10, CEACAMP3, DNAJC19P2, CEACAM4, DNAJC19P3, AC243960.5, AC243960.4, CEACAM7, CEACAM5, AC243967.1, CEACAM6, AC243967.2, CEACAM3, HNRNPA1P52, AC243967.3, LYPD4, DMRTC2, RPS19, MIR6797, CD79A.
- chr19:46,189,029–58,605,223, 897 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr20:58,515,379–64,327,972, 193 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,675. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
